Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A0YX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A0YX-01A (Primary Tumor).

CLINICAL DIAGNOSIS AND HISTORY

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Bladder cancer.
PROCEDURE: Cystectomy/Indiana pouch.
SPECIFIC CLINICAL QUESTION: Not stated.
OUTSIDE TISSUE DIAGNOSIS: Not stated.
PRIOR MALIGNANCY: Not stated.
CHEMORADIATION: Not stated.
ORGAN TRANSPLANT: Not stated.
IMMUNOSUPPRESSION: Not stated.
OTHER DISEASES: Not stated.

SPECIMEN(S) RECEIVED:

- 1: Right Pubic Margin FS
- 2: Right Ureter Margin FS
- 3: Left Ureter Margin FS
- 4: Bladder, Uterus, Fallopian Tubes, Ovaries
- 5: Right Pelvic Lymph Node
- 6: Left Pelvic Lymph Node
- 7: Appendix

100-0-3

Carcinoma, urothelial, NOS 8120/3

Path Site: bladder wall, NOS C67.9

hw 11/20/11

FINAL DIAGNOSIS

PART 1: SOFT TISSUE, RIGHT PUBIC MARGIN, EXCISION -
UROTHELIAL CARCINOMA INFILTRATING INTO SOFT TISSUE.

PART 2: URETER, RIGHT MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN REACTIVE UROTHELIUM.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 3: URETER, LEFT MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN REACTIVE UROTHELIUM.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 4:

BLADDER, VAGINA, UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES, ANTERIOR PELVIC EXENTERATION -

- A. INVASIVE UROTHELIAL CARCINOMA, HIGH GRADE (WHO/ISUP), WITH SQUAMOUS DIFFERENTIATION.
- B. THE CARCINOMA MEASURES 5.0 CM IN GREATEST DIMENSION.
- C. THE CARCINOMA EXTENSIVELY INVOLVES THE PERIVESICAL ADIPOSE TISSUE.
- D. THE INKED SURGICAL RESECTION MARGIN IS POSITIVE IN THE RIGHT LATERAL AND POSTERIOR REGIONS (SLIDES 4L AND 4M).
- E. PERINEURAL INVASION IS IDENTIFIED.
- F. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. UTERUS WITH MULTIPLE LEIOMYOMATA UP TO 3.5 CM.
- H. UNREMARKABLE BILATERAL OVARIES AND BILATERAL FALLOPIAN TUBES.
- I. TNM PATHOLOGIC STAGING = pT3b N0 MX.

PART 5: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF METASTATIC CARCINOMA IN FOURTEEN LYMPH NODES EXAMINED (0/14).

PART 6: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF METASTATIC CARCINOMA IN EIGHT LYMPH NODES EXAMINED (0/8).

PART 7: APPENDIX, APPENDECTOMY -

BENIGN UNREMARKABLE APPENDIX WITH FIBROUS OBLITERATION OF THE TIP AND MID-PORTION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

Anterior exenteration

TUMOR SITE:

Right lateral wall, Anterior wall

TUMOR SIZE:

Greatest dimension: 5.0 cm

Additional dimensions: 5.0 x 2.0 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma with squamous differentiation

ASSOCIATED EPITHELIAL LESIONS:

None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Solid/nodule, Ulcerated

PATHOLOGIC STAGING (pTNM):

pT3b

pN0

Number of nodes examined: 22

Number of nodes involved: 0

pMX

MARGINS:

Margin(s) involved by invasive carcinoma

Margin(s): Right lateral and posterior resection margins

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Present

DIRECT EXTENSION OF INVASIVE TUMOR:

Perivesical fat

I-IPAA Discrepancy		☒

Source: NCI Genomic Data Commons file d9d442fa-5f4d-487d-8f71-e8d22169ba15 (TCGA-BT-A0YX.C628DA27-9908-48F3-B191-99C9248774C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).